Somatic mutation profile of tumor specimen TCGA-D1-A3DH-01A (aliquot TCGA-D1-A3DH-01A-11D-A19Y-09) from TCGA case TCGA-D1-A3DH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,935 days).
Specimen TCGA-D1-A3DH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) add1245f-26a8-493f-be76-012aa5abe9c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A3DH-10A (Blood Derived Normal), aliquot TCGA-D1-A3DH-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4d09121-9672-46d7-a6fd-716dbfb47178

The open-access MAF lists 100 somatic variants for this specimen: 78 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 18, Nonsense Mutation 6, Intron 2, Frame Shift Del 2, 3'Flank 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 63/191 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 170/181 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.898C>G p.L300V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.436); catalogued as COSV99717454; called by muse, mutect2, varscan2
- AKNAD1 | c.1369G>C p.D457H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100645272, COSV62198648; called by muse, mutect2, varscan2
- ARHGEF40 | c.4241G>C p.R1414T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.831); catalogued as COSV100069960; called by muse, mutect2
- ASNS | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51555996, COSV99445908; called by muse, mutect2, varscan2
- AVPR1A | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV100146763; called by muse, mutect2, varscan2
- B3GALT2 | c.260T>A p.V87D | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100813557; called by muse, mutect2, varscan2
- BCL7A | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1020885531, COSV99946744; called by muse, mutect2, varscan2
- BPIFB3 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs138919082; called by muse, varscan2
- BRWD1 | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100312730; called by muse, mutect2, varscan2
- C2orf49 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs765886202, COSV51527164; called by muse, mutect2
- CCNI | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779499819, COSV52959606; called by muse, mutect2, varscan2
- CHL1 | c.3619C>T p.R1207W (on ENST00000397491 / NM_001253387.1; = p.R1223W on NM_006614.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs866660471, COSV56586680; called by muse, mutect2, varscan2
- CLUL1 | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100093660; called by muse, mutect2, varscan2
- COL11A2 | c.4250G>A p.G1417E (on ENST00000341947 / NM_080680.3; = p.G1310E on NM_080679.2) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100553394; called by muse, mutect2, varscan2
- COL28A1 | c.2317C>A p.L773I | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101258292; called by muse, mutect2, varscan2
- COQ3 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV99632446, COSV99632777; called by muse, mutect2, varscan2
- CTBP1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1390818109, COSV99337427; called by muse, mutect2
- DNAH6 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV99404624; called by muse, mutect2, varscan2
- DNAH7 | c.5263C>A p.H1755N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100413753; called by muse, mutect2, varscan2
- DST | c.18949G>C p.D6317H (on ENST00000361203 / NM_001374722.1; = p.D4014H on NM_015548.5) | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55028579; called by muse, mutect2, varscan2
- EFCAB13 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs768738134, COSV100516330, COSV100516524; called by muse, mutect2, varscan2
- ENPP1 | c.2109C>G p.F703L | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.062); catalogued as COSV100719368, COSV62930937; called by muse, mutect2, varscan2
- FAM135A | c.3679C>G p.P1227A (on ENST00000370479 / NM_001351599.1; = p.P1014A on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV99525173, COSV99526145; called by muse, mutect2, varscan2
- FBXW7 | c.1496G>A p.G499D (on ENST00000281708 / NM_001349798.2; = p.G419D on NM_018315.5) | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55900537, COSV99654214; called by muse, mutect2, varscan2
- FLNA | c.7288G>A p.G2430S (on ENST00000369850 / NM_001110556.2; = p.G2422S on NM_001456.3) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.517); catalogued as COSV100774257; called by muse, mutect2, varscan2
- FREM1 | c.3592G>A p.D1198N | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772523599, COSV66528833; called by muse, mutect2, varscan2
- GARRE1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs769875704, COSV100208997; called by muse, mutect2, varscan2
- HCLS1 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV100100303; called by muse, mutect2, varscan2
- HLA-F | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.84); catalogued as rs759235225, COSV99465598; called by muse, mutect2, varscan2
- IMPACT | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99408757; called by muse, mutect2
- IPO13 | c.1966C>T p.H656Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100961037; called by muse, mutect2
- ITPRID2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.382); catalogued as COSV100237837; called by muse, mutect2, varscan2
- KANK1 | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV100619419; called by muse, mutect2, varscan2
- KAT2B | c.2457C>G p.F819L | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV99768816; called by muse, mutect2, varscan2
- MAMDC2 | c.919T>A p.F307I | Missense Mutation (SNP) | VAF 68/79 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101015196; called by muse, mutect2, varscan2
- MAPK1 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV99307763; called by muse, mutect2, varscan2
- MARCHF6 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 89/448 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV99929321; called by muse, mutect2, varscan2
- MCC | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1434634256, COSV101342710, COSV68727315; called by muse, mutect2, varscan2
- MNAT1 | c.88_89del p.C31* | Frame Shift Del (DEL) | VAF 31/126 reads (25%) | catalogued as rs756099490; called by pindel, varscan2
- MTUS1 | c.2425G>C p.E809Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV100028851; called by muse, mutect2, varscan2
- NAALADL2 | c.570T>A p.N190K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV101458163; called by muse, mutect2, varscan2
- NAV3 | c.6964G>C p.E2322Q (on ENST00000397909 / NM_001024383.2; = p.E2300Q on NM_014903.6) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as COSV99886701; called by muse, mutect2, varscan2
- NRXN1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100453094; called by muse, mutect2, varscan2
- NSUN2 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99242897; called by muse, mutect2, varscan2
- OR10H2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1459823672, COSV100008612; called by muse, mutect2, varscan2
- OR4Q3 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV59178170; called by muse, mutect2, varscan2
- OR5R1 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV100393239, COSV56571547; called by muse, varscan2
- ORC4 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298062783, COSV99931942; called by muse, mutect2, varscan2
- PCDHA5 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100972078, COSV65352193; called by muse, mutect2, varscan2
- PCDHGA2 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53918466, COSV53933002; called by muse, mutect2, varscan2
- PDE10A | c.1502C>G p.S501C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV63101986; called by muse, mutect2
- PELO | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99250614; called by muse, mutect2, varscan2
- PKHD1L1 | c.9642C>G p.I3214M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101005270, COSV101006883, COSV65739814; called by muse, mutect2, varscan2
- PLA2G4A | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100820345; called by muse, mutect2, varscan2
- RPS5 | c.93T>A p.N31K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV99544770; called by muse, mutect2, varscan2
- RYR2 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV100767628; called by muse, mutect2, varscan2
- SAMD9 | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as COSV101180124, COSV101180406; called by muse, mutect2, varscan2
- SAMD9L | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs748003916, COSV100560278, COSV59081239; called by muse, mutect2, varscan2
- SCMH1 | c.1333T>C p.Y445H (on ENST00000326197 / NM_001031694.2; = p.Y398H on NM_012236.4) | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100401331; called by muse, mutect2, varscan2
- SEPTIN3 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99351910; called by muse, mutect2, varscan2
- SLC25A44 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs140016645; called by muse, mutect2, varscan2
- SLC5A6 | c.1008C>A p.F336L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100142988, COSV60158315; called by muse, mutect2, varscan2
- STAU2 | c.491G>A p.R164Q (on ENST00000524300 / NM_001164380.2; = p.R132Q on NM_014393.2) | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as COSV100868986; called by muse, mutect2, varscan2
- SYT13 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99194638; called by muse, mutect2, varscan2
- TAF1 | c.2795G>A p.G932E (on ENST00000373790 / NM_138923.4; = p.G953E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334355; called by muse, mutect2, varscan2
- TCEANC | c.862G>C p.D288H (on ENST00000380600 / NM_001297563.2; = p.D318H on NM_152634.4) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as COSV100124543; called by muse, mutect2, varscan2
- TGFBRAP1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020232911, COSV51513611; called by muse, mutect2, varscan2
- TRPS1 | c.1852C>T p.Q618* (on ENST00000220888 / NM_001330599.2; = p.Q631* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/158 reads (22%) | catalogued as COSV55236763; called by muse, mutect2, varscan2
- USH2A | c.12904A>G p.R4302G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1437342089, COSV100228568; called by muse, mutect2, varscan2
- VCL | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV99280386; called by muse, mutect2, varscan2
- VTA1 | c.179T>A p.L60* | Nonsense Mutation (SNP) | VAF 78/99 reads (79%) | catalogued as COSV100859167; called by muse, mutect2, varscan2
- ZDHHC7 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100568696; called by muse, varscan2
- ZNF678 | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs779175623, COSV100652572; called by muse, mutect2, varscan2
- GTF2I | c.1199_1201del p.E400del (on ENST00000573035 / NM_032999.4; = p.E359del on NM_001518.5) | In Frame Del (DEL) | VAF 189/269 reads (70%) | called by mutect2, pindel, varscan2
- PHB2 | c.264_286del p.K89Qfs*23 | Frame Shift Del (DEL) | VAF 73/245 reads (30%) | called by mutect2, pindel, varscan2
- USP19 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASP5 | c.1002C>T p.L334= | Silent (SNP) | VAF 65/102 reads (64%) | catalogued as COSV99507123; called by muse, mutect2, varscan2
- CES3 | c.648C>T p.F216= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs768694829, COSV57592693; called by muse, mutect2, varscan2
- CTR9 | c.63C>T p.F21= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs755268144, COSV63728297; called by muse, mutect2, varscan2
- DNAJC21 | c.1440C>G p.V480= | Silent (SNP) | VAF 28/251 reads (11%) | catalogued as COSV100331272; called by muse, mutect2, varscan2
- GADD45GIP1 | c.642A>G p.P214= | Silent (SNP) | VAF 52/94 reads (55%) | catalogued as COSV100379797; called by muse, mutect2, varscan2
- ISOC1 | c.777G>C p.V259= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99434342; called by muse, mutect2, varscan2
- LHCGR | c.1914G>T p.L638= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1310178968, COSV54299720; called by muse, mutect2, varscan2
- MRGPRX3 | c.231C>T p.S77= | Silent (SNP) | VAF 68/80 reads (85%) | catalogued as rs752938397, COSV101283481; called by muse, varscan2
- MYLK | c.720G>T p.G240= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as COSV100658480, COSV60610685; called by muse, mutect2, varscan2
- NUP210L | c.5331C>T p.L1777= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as COSV99667164; called by muse, mutect2, varscan2
- OAT | c.1002C>T p.I334= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs757744354, COSV100920352; called by muse, mutect2, varscan2
- OSMR | c.969C>T p.I323= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as rs1334576843, COSV57087555; called by muse, mutect2
- PCDHGA3 | c.1008G>A p.T336= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV54049582; called by muse, mutect2, varscan2
- PIP4K2A | c.858C>T p.A286= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs553184076, COSV60542695; called by muse, varscan2
- SFI1 | c.1194C>T p.H398= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as rs373790208; called by muse, mutect2, varscan2
- SLC9C2 | c.2625C>T p.L875= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs755694698, COSV100876551, COSV62948032; called by muse, mutect2, varscan2
- TRERF1 | c.411C>T p.S137= | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as rs368963810; called by muse, mutect2, varscan2
- VPS36 | c.621T>C p.G207= | Silent (SNP) | VAF 157/171 reads (92%) | catalogued as COSV100955119; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701002 G>A | 3'Flank (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- HOXD4 | chr2:176150317 G>A | 5'Flank (SNP) | VAF 28/48 reads (58%) | catalogued as rs570521775; called by muse, mutect2, varscan2
- PPP2R5C | c.93+23160C>G | Intron (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100159043; called by muse, mutect2, varscan2
- SV2C | c.581-21099C>G | Intron (SNP) | VAF 41/136 reads (30%) | called by muse, mutect2, varscan2
